Somatic mutation profile of tumor specimen TCGA-DX-AB37-01A (aliquot TCGA-DX-AB37-01A-11D-A417-09) from TCGA case TCGA-DX-AB37, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 73.1 years (26,696 days).
Specimen TCGA-DX-AB37-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4436aec-7684-4be1-9844-3b6e6152d4f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB37-10A (Blood Derived Normal), aliquot TCGA-DX-AB37-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b933ca7-2103-414d-8f95-70287c651013

The open-access MAF lists 55 somatic variants for this specimen: 37 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 15, 3'Flank 3, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP10 | c.197C>G p.A66G | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.991); catalogued as COSV99855611; called by muse, mutect2, varscan2
- APC | c.7706G>A p.S2569N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99970472; called by muse, mutect2, varscan2
- APOB | c.9986T>C p.I3329T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99268348; called by muse, mutect2, varscan2
- ATP1A4 | c.3052C>T p.H1018Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762962960, COSV100927372; called by muse, varscan2
- ATRX | c.5448+2T>A p.X1816_splice | Splice Site (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100971519; called by muse, mutect2, varscan2
- CAPRIN2 | c.922T>G p.L308V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.969); catalogued as COSV99195729; called by muse, mutect2, varscan2
- CD163L1 | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100550705; called by muse, mutect2, varscan2
- CLNK | c.380C>G p.T127R | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.497); catalogued as COSV99905949; called by muse, mutect2, varscan2
- CNIH3 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs755612701, COSV99686283; called by muse, mutect2, varscan2
- DRD3 | c.815G>T p.R272I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV99879716; called by muse, mutect2, varscan2
- ERICH3 | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as rs1226872584, COSV100445921; called by mutect2, varscan2
- ESX1 | c.572G>T p.R191I | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101006515; called by muse, mutect2, varscan2
- GDPD2 | c.60C>G p.S20R | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100978715; called by muse, mutect2, varscan2
- HMCES | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.207); catalogued as COSV101077405; called by muse, varscan2
- HSD17B2 | c.806T>A p.I269N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99556850; called by muse, mutect2, varscan2
- INTU | c.2622C>A p.N874K | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs1458207780, COSV100081431; called by muse, mutect2, varscan2
- METTL21C | c.132A>T p.E44D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99940154; called by muse, mutect2, varscan2
- METTL23 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); catalogued as COSV100373345; called by muse, mutect2
- NOB1 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs543289898, COSV52064021; called by muse, varscan2
- NOB1 | c.671G>A p.C224Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99264102; called by muse, varscan2
- NUDT21 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as COSV100273185; called by muse, mutect2, varscan2
- OR51A4 | c.484C>A p.P162T | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1283537431, COSV100985381, COSV66749859; called by muse, mutect2, varscan2
- PLS1 | c.892T>A p.S298T | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100538375; called by muse, mutect2, varscan2
- POLQ | c.7222G>T p.D2408Y | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99953061; called by muse, mutect2, varscan2
- PPP2R5C | c.998A>C p.K333T | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV100160102; called by muse, mutect2, varscan2
- SLC35G5 | c.100T>A p.S34T | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV99644634; called by muse, mutect2, varscan2
- SLC9C2 | c.401T>A p.I134K | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100877025; called by muse, mutect2, varscan2
- SLCO6A1 | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | catalogued as COSV101135057; called by muse, mutect2, varscan2
- TBX18 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100858596; called by muse, mutect2, varscan2
- TRIO | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs139892017; called by muse, mutect2
- VTN | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99879785, COSV99879847; called by muse, mutect2, varscan2
- XIRP2 | c.2708G>T p.S903I (on ENST00000628543; = p.S1078I on NM_152381.6) | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV99747966; called by muse, mutect2, varscan2
- ZBTB41 | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV100963471; called by muse, mutect2, varscan2
- ZBTB41 | c.2398C>G p.Q800E | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100963473, COSV66358906; called by muse, mutect2, varscan2
- ZNF292 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.092); catalogued as COSV100371379; called by muse, mutect2, varscan2
- STK24 | c.151_166del p.F51Ifs*9 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel
- TUT1 | c.2600del p.P867Lfs*17 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | called by mutect2, pindel, varscan2
- AQP4 | c.885A>G p.K295= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV101270570; called by muse, mutect2, varscan2
- ARAP2 | c.3225G>A p.G1075= | Silent (SNP) | VAF 24/165 reads (15%) | catalogued as rs1313205933, COSV100395307; called by muse, mutect2, varscan2
- GTF3C1 | c.2004G>A p.E668= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100649754; called by muse, mutect2, varscan2
- JPH1 | c.984G>A p.E328= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1563424251, COSV100646802; called by muse, mutect2, varscan2
- MAS1L | c.147C>T p.G49= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs776150381, COSV101009682, COSV65809297; called by muse, mutect2, varscan2
- NOB1 | c.390G>A p.L130= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as rs755647027, COSV99264104; called by muse, mutect2, varscan2
- OR4K14 | c.621T>A p.L207= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100520538; called by muse, mutect2, varscan2
- PADI1 | c.81G>A p.V27= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100969292; called by muse, mutect2
- QSER1 | c.2394C>A p.L798= (on ENST00000399302; = p.L927= on NM_001076786.3) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV101234974; called by muse, mutect2, varscan2
- RELN | c.6588C>T p.I2196= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as rs753704714, COSV59037178; called by muse, mutect2, varscan2
- RNF213 | c.2031G>A p.V677= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100174025; called by muse, varscan2
- SYNJ1 | c.4791G>A p.T1597= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs763042220, COSV100449692; called by muse, mutect2, varscan2
- TJP1 | c.1164G>A p.V388= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV100633220; called by muse, varscan2
- TRIM4 | c.978G>T p.G326= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100584427; called by muse, mutect2, varscan2
- ZDBF2 | c.6684G>T p.S2228= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs769931510, COSV100985602, COSV65624129; called by muse, mutect2, varscan2
- TRPV2 | chr17:16439184 G>A | 3'Flank (SNP) | VAF 16/91 reads (18%) | called by muse, varscan2
- TRPV2 | chr17:16439514 G>A | 3'Flank (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- TRPV2 | chr17:16440188 G>A | 3'Flank (SNP) | VAF 22/101 reads (22%) | catalogued as rs755357352; called by muse, mutect2, varscan2
